Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4849, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4849-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, LEFT, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE, FUHRMAN NUCLEAR GRADE 3 OF 4 (See comment).
- B. RENAL CELL CARCINOMA GROWS IN A SOLID PATTERN OF GROWTH.
- C. GREATEST DIAMETER OF THE NEOPLASM IS 13.5 CM.
- D. THE NEOPLASM EXTENDS THROUGH THE RENAL CAPSULE INTO PERIRENAL FAT, BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- E. MICROSCOPIC INVASION OF A BRANCH OF THE RENAL VEIN IS PRESENT (slide N).
- F. ALL SURGICAL MARGINS OF RESECTION ARE FREE OF NEOPLASM.
- G. NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- H. ADRENAL GLAND IS UNREMARKABLE.
- I. NO LYMPH NODES ARE IDENTIFIED.
- J. TNM STAGE: pT3a NX MX.
- K. TNM HISTOLOGICAL GRADE: G2.

Source: NCI Genomic Data Commons file 1971fb88-8b2f-4fc2-95fc-ac7e19b41f3d (TCGA-B0-4849.68C63115-54E2-4240-A3D5-559BACF37284.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).